Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5192, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5192-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Right renal mass.

TCGA - BP - 5192

Specimens Submitted:

1: SP: KIDNEY, RIGHT, PARTIAL NEPHRECTOMY

2: SP: KIDNEY, RIGHT, DEEP SURGICAL MARGIN #2, BIOPSY

DIAGNOSIS:

1. SP: KIDNEY, RIGHT, PARTIAL NEPHRECTOMY:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 2.7 cm

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Also see part 2

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

2. SP: KIDNEY, RIGHT, DEEP SURGICAL MARGIN #2, BIOPSY:

- Renal cell carcinoma, conventional (clear cell) type, present on one surface of the unoriented tissue

- The other surface is free of tumor

[page 2 of 2]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIALS)

Gross Description:

1). The specimen is received fresh for frozen section consultation labeled "Right renal tumor". It consists of a portion of kidney measuring 4.2 x 4.0 x 2.7 cm. The resected margin is inked black. On cut section of the specimen there is a well-circumscribed, partially cystic, hemorrhagic brown-tan mass measuring 2.7 x 2.5 x 2.1 cm. It is 0.1 cm from the black inked surface and abuts the capsular surface but does not grossly extend to the perinephric fat. Representative section of the nodule is submitted for frozen section consultation. The sample is given to TPS. Representative sections are submitted.

Summary of sections:

FSC -- frozen section control

T-tumor

TF-tumor with fat

TM-tumor with margin

2). The specimen is received in formalin labeled "Deep surgical margin number two right kidney". It consists of a single piece of brown-tan renal tissue measuring 1.3 x 0.7 x 0.6 cm, which is bisected and entirely submitted.

Summary of sections:

U-undesignated

Summary of Sections:

Part 1: SP: KIDNEY, RIGHT, PARTIAL NEPHRECTOMY

Block	Sect. Site	PCs
1	fsc	1
1	t	1
1	tf	1
1	tm	1

Part 2: SP: KIDNEY, RIGHT, DEEP SURGICAL MARGIN #2, BIOPSY

Block	Sect. Site	PCs
1	u	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: SP: RIGHT RENAL TUMOR MARGIN FREE OF TUMOR. RENAL CORTICAL NEOPLASM.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file a28d8813-bb18-4264-ba77-2d3551cffa9f (TCGA-BP-5192.63D0AB58-DDC3-42CC-99EC-0EF4F24F24F8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).